Somatic mutation profile of tumor specimen BA2806D (aliquot aq-BA2806D) from BEATAML1.0 case 2285, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 42.1 years (15,367 days).
Specimen BA2806D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d1c6194b-e486-4bfb-8419-a79599f4ea98.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2411D (Solid Tissue Normal), aliquot aq-BA2411D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ed003aa7-d532-4f99-b186-b38efb0af960

The open-access MAF lists 6 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 2, Frame Shift Ins 2, 3'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FARSA | c.437dup p.Q147Tfs*3 | Frame Shift Ins (INS) | VAF 32/96 reads (33%) | catalogued as rs746493788; called by mutect2, varscan2
- ZNF687 | c.2815dup p.R939Pfs*36 | Frame Shift Ins (INS) | VAF 16/58 reads (28%) | catalogued as rs749403447; called by mutect2, varscan2
- KDM1A | c.1771C>A p.R591= | Silent (SNP) | VAF 4/56 reads (7%) | catalogued as COSV63088329; called by muse, mutect2
- PCDHA13 | c.2263C>A p.R755= | Silent (SNP) | VAF 3/51 reads (6%) | catalogued as COSV56492665; called by muse, mutect2
- FYCO1 | chr3:45915608 C>A | 3'Flank (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- NDUFA5 | c.66+589G>T | Intron (SNP) | VAF 4/47 reads (9%) | called by muse, mutect2
